Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EJ-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site Code: Liver C22.0

1/19/11

lw

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Specimen: A1 A2 A3 A4 A5 A6 A7

Right lobe liver (20.0 x 15.0 x 12.0 cm) with gallbladder (8.5 x 3.0 x 2.2 cm) together weighing 1590.0 grams.

DIAGNOSIS:

Liver, right lobe with gallbladder, resection: Grade 2 (of 4) well-differentiated hepatocellular carcinoma forming a tan-green nodular, poorly circumscribed solitary mass (14.2 x 12.0 x 11.8 cm). The tumor is partially encapsulated and shows a broad pushing-type border with the adjacent non-neoplastic parenchyma. No satellite masses are identified. No large vein invasion is identified. The tumor extends up to but does not involve the gallbladder muscular wall. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.3 cm). The gallbladder mucosa is unremarkable. The non-neoplastic liver will be reviewed on permanent sections and will be reported in an addendum.

ADDENDUM:

The permanent sections of the non-neoplastic liver are reviewed. The portal areas present show only minimal patchy non-specific inflammation. Numerous portal areas are totally unremarkable. The interlobular bile ducts are intact and show no significant cellular injury. No significant ductular proliferation is identified. The hepatic lobular parenchyma is essentially unremarkable. No significant steatosis is identified. No significant necroinflammatory activity is noted. Apoptotic hepatocytes are inconspicuous. The PAS stain after diastase digestion demonstrates no significant cytoplasmic globular inclusions within hepatocytes. The iron stain demonstrates no significant iron accumulation within

hepatocytes or Kupffer cells. The trichrome stain highlights the portal areas and demonstrates no significant portal tract expansion by fibrosis and specifically no periportal or pericellular fibrosis is identified.

[page 2 of 4]
Patient Key:
Surgical date:

TISSUE DESCRIPTION:

Cut A1 A2 A3 A4 A5 A6 A7
Right lobe liver (20.0 x 15.0 x 12.0 cm) with gallbladder (8.5 x 3.0 x 2.2 cm) together weighing 1590.0 grams.

DIAGNOSIS:

Liver, right lobe with gallbladder, resection: Grade 2 (of 4) well-differentiated hepatocellular carcinoma forming a tan-green nodular, poorly circumscribed solitary mass (14.2 x 12.0 x 11.8 cm). The tumor is partially encapsulated and shows a broad pushing-type border with the adjacent non-neoplastic parenchyma. No satellite masses are identified. No large vein invasion is identified. The tumor extends up to but does not involve the gallbladder muscular wall. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.3 cm). The gallbladder mucosa is unremarkable. The non-neoplastic liver will be reviewed on permanent sections and will be reported in an addendum.

ADDENDUM:

The permanent sections of the non-neoplastic liver are reviewed. The portal areas present show only minimal patchy non-specific inflammation. Numerous portal areas are totally unremarkable. The interlobular bile ducts are intact and show no significant cellular injury. No significant ductular proliferation is identified. The hepatic lobular parenchyma is essentially unremarkable. No significant steatosis is identified. No significant necroinflammatory activity is noted. Apoptotic hepatocytes are inconspicuous. The PAS stain after diastase digestion demonstrates no significant cytoplasmic globular inclusions within hepatocytes. The iron stain demonstrates no significant iron accumulation within hepatocytes or Kupffer cells. The trichrome stain highlights the portal areas and demonstrates no significant portal tract expansion by fibrosis and specifically no periportal or pericellular fibrosis is identified.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: ResectionPatient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): right lobe
☐ Multiple (specify location): _____

Tumor SizeGreatest dimension: 14.2 cm*Additional dimensions: 2.0 x 11.8 cm☐ Cannot be determined (see Comment)**MICROSCOPIC****Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☒ GII: Moderately differentiated
☐ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
- ☒ pT0: No evidence of primary tumor
- ☒ pT1: Solitary tumor with no vascular invasion
- ☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
- ☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
- ☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
- ☐ pN0: No regional lymph node metastasis
- ☐ pN1: Regional lymph node metastasis

Specify: Number examined:

Number involved:

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
- ☐ pM1: Distant metastasis

*Specify site(s), if known:

Margins (check all that apply)

Parenchymal Margin

- ☒ Cannot be assessed
- ☒ Uninvolved by invasive carcinoma
- Distance of invasive carcinoma from closest margin: 2.0 mm
- Specify margin:
- ☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
- ☐ Uninvolved by invasive carcinoma
- * ☐ Carcinoma in situ absent
- * ☐ Carcinoma in situ present
- ☐ Involved by invasive carcinoma

Other Margin

- Specify margin:
- ☐ Cannot be assessed
- ☐ Uninvolved by invasive carcinoma
- ☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☒ Absent
- * ☐ Present
- * ☐ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
- * ☐ Hepatocellular dysplasia
- * ☐ Ductal dysplasia
- * ☐ Cirrhosis/fibrosis
- * ☐ Iron overload
- * ☐ Hepatitis (specify type):
- * ☒ Other (specify): only minimal patchy nonspecific inflammation in portal areas

Source: NCI Genomic Data Commons file fa4ec55b-d02c-4583-a3b0-9a1d646cf7e7 (TCGA-DD-A1EJ.A34C7F12-5EB1-4B7C-890C-FD2DFF41E85C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).